Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TA, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TA-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, papillary
urothelial 8/30/13
Site ^{overly} lateral wall & lobe 8/67.2
path Bladder NOS 667.9

Sample #
Gender: Male
DOB:
Race: White
Report Date:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

- A. Right pelvic lymph nodes:
- One of seven lymph nodes with metastatic urothelial carcinoma (1/7; non-frozen node).
- One focus of urothelial carcinoma in perinodal fibroadipose tissue.
- B. Left pelvic lymph nodes:
- One lymph node with metastatic urothelial carcinoma (1/1).
- C. Right pelvic lymph nodes:
- Two of five lymph nodes with metastatic urothelial carcinoma (2/5).
- D. Left pelvic lymph nodes:
- Two of fourteen lymph nodes with metastatic urothelial carcinoma (2/14).
- E. Bladder, prostate, cystoprostatectomy:
- Papillary urothelial carcinoma, high-grade, invasive of extravesicular soft tissue.
- Prostatic adenocarcinoma.
- See parameters below
- F. Right distal ureter:
- Ureter, no evidence of tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Papillary urothelial carcinoma
2. Grade of tumor: High grade
3. Depth of invasion: Extravesicular soft adipose tissue (A5, E15)
4. Tumor distribution:
- Multifocal, 6 x 3 x 2 cm largest size
- dome
- right lateral wall
- left lateral wall
- trigone
- anterior wall
- posterior wall

Extensive vascular invasion

5. Ureteral Margins: Negative
6. Distal urethral margin: Negative
7. Lymph nodes: Six of 27 (6/27) lymph nodes with metastatic carcinoma
8. pTNM: pT3b, N2, MX

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+3
2. Perineural Invasion: Absent
3. Tumor Location:
- Peripheral zone - right and left
4. Tumor Volume Estimate: 20%
5. High-grade P.I.N.: Focal
6. Seminal Vesicles: Negative for tumor
7. Fibromuscular Capsule: Tumor confined to the prostate.
8. Peripheral Margin: Negative for tumor
9. Distal (apical) Margin: Negative for tumor
10. Proximal (basilar) Margin: Negative for tumor
11. Regional Lymph Nodes (right and left): Negative for tumor
12. pTNM: pT2c, N0, MX

[page 2 of 3]
Interpretation performed by the Attending Pathologist and reviewed with the Resident or Fellow.
Electronically Signed Out by

Clinical History:

The patient is a year-old male with history of bladder cancer who undergoes radical cystectomy and ONB.

Specimens Received:

A: Right pelvic lymph node
B: Left Pelvic Lymph Node
C: Rt. Pelvic Lymph Node
D: Left pelvic lymph node
E: Bladder, prostate, vas deferense
F: Right Distal Ureter

Gross Description:

Received are six containers bearing the patient's name and medical record number.

A. The first container is additionally labeled "right pelvic lymph node". Received fresh for intraoperative diagnosis is a 4 x 4 x 2 cm aggregate of yellow, lobulated fibroadipose tissue. The firmest lymph node is frozen and read as "lymph node, no tumor" by Dr. []. Additionally identified are seven lymph nodes ranging in size from 0.3-2.0 cm in greatest dimension. Representative sections are submitted as follows:

A1FS: frozen section remnant
A2: four lymph nodes
A3: one lymph node
A4: one lymph node
A5: one matted lymph node, quadriseected

B. The second container is additionally labeled "left pelvic lymph node". Received fresh for intraoperative diagnosis is a 1.5 cm yellow-tan nodule grossly consistent with lymph node. It is bisected, frozen and read as "metastatic urothelial carcinoma" by Dr. []. It is entirely submitted in cassette B1FS.

C. The third container is additionally labeled "right pelvic lymph node". Received fresh is a 5 x 3 x 1 cm aggregate of yellow, lobulated fibroadipose tissue. Identified are five lymph node candidates ranging in size from 0.5-2.0 cm in greatest dimension. Representative sections are submitted as follows:

C1: two lymph nodes
C2: two lymph nodes
C3: one lymph node

D. The fourth container is additionally labeled "left pelvic lymph node". Received fresh and placed in formalin is a 6 x 4 x 1 cm aggregate of yellow, lobulated fibroadipose tissue. Identified are 15 lymph node candidates ranging in size from 0.2-2.5 cm in greatest dimension. Representative sections are submitted as follows:

D1: four lymph nodes
D2: two lymph nodes
D3: three lymph nodes
D4: three lymph nodes
D5: one lymph node, bisected
D6: one lymph node, bisected

[page 3 of 3]
D7: one lymph node, bisected

E. The fifth container is additionally labeled "bladder, prostate, vas deferens". Received fresh and placed in formalin is a 14 x 5.9 x 4 cm cystoprostatectomy specimen with attached mesenteric fat. The prostate measures 5 x 4 x 3.5 cm. The left seminal vesicle measures 2.5 x 1 cm and the left vas deferens 2.5 x 0.5 cm. The right seminal vesicle measures 4 x 1.5 cm and the right vas deferens 3 x 0.5 cm. The right half of the prostate is inked blue and the left half is inked black. The bladder measures 6 x 6 x 8 cm. The right and left ureteral stumps measure 2 x 0.4 cm and 2.4 x 0.6 cm, respectively. The anterior and posterior surfaces of the bladder are inked black. The bladder is opened anteriorly along the urethra using a Y-shaped incision and reveals tan-brown, glistening, wrinkled mucosa over the dome. The remainder of the bladder demonstrates a firm, white-tan, poorly circumscribed, irregularly shaped, granular, friable mass. It is grossly based on the anterior wall but extends around the lateral walls to the posterior wall in an almost circumferential manner. It measures 6 x 3 x 2 cm. There are also two 0.3-0.5 cm, circular, raised, white-tan plaques on the dome. The prostate and bladder are serially sectioned. The largest mass grossly invades through the right and left lateral walls of the bladder to a maximum depth of 2.1 cm. It is apparent at the inked margins of the right and left lateral walls. The mass also invades through the posterior wall, inferiorly at the trigone to a depth of 0.7 cm, 1 cm away from the nearest black inked margin. Multiple phleboliths are identified.

Also received is a 6 x 4 x 3 cm aggregate of yellow, lobulated fibroadipose tissue that is detached from the main specimen. Identified is one firm nodule measuring 2 cm in greatest dimension. It is bisected to reveal a nodular, well-circumscribed, white-yellow mass. Representative sections are submitted as follows:

- E1: distal urethral margin
- E2: left ureteral margin
- E3: right ureteral margin
- E4: small plaque and adjacent normal dome
- E5: larger plaque and adjacent normal dome
- E6: normal anterior wall and normal posterior wall, posterior inked black
- E7: trigone, posterior wall
- E8: left lateral/anterior wall
- E9: right lateral/anterior wall
- E10: left wall and prostate
- E11: right wall and prostate
- E12,E13: representative prostate
- E14: representative bilateral seminal vesicles and vasa deferentia
- E15,E16: extravesicular nodule bisected
- E17,E18: left ureteral margin candidates
- E19: left ureteral margin candidate

Please note E8 is decalcified due to calcific vessels. Please note gross photographs are taken.

F. The sixth container is additionally labeled "right distal ureter stitch on non-margin side". Received fresh and placed in formalin is a 0.5 cm tubular structure with an external diameter of 0.4 cm and a pinpoint lumen. A stitch is identified at the non-margin side. The margin side is removed and submitted face down in cassette F1. The remainder is serially sectioned and entirely submitted in cassette F2.

Intraoperative Consult Diagnosis:

- AIFS. Right pelvic lymph node: Lymph node, no tumor.
- BIFS. Left pelvic lymph node: Metastatic urothelial carcinoma.

HPA Discrepancy		✓
Dual/Synchronous Primary	Prostate ✓	

Source: NCI Genomic Data Commons file b5b52fcb-66e3-4389-b282-f318fa553420 (TCGA-FD-A6TA.876F967E-2CC2-4AFA-9BE7-23D77F6531E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).